Somatic mutation profile of tumor specimen ALCH-B21S-TTP1-A (aliquot ALCH-B21S-TTP1-A-2-0-D-A76N-36) from ALCHEMIST case ALCH-B21S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 49.8 years (18,188 days).
Specimen ALCH-B21S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfa7fa35-2271-48fc-91e8-cb07e7cd8511.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B21S-NB1-A (Blood Derived Normal), aliquot ALCH-B21S-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/793ce08b-391f-43cb-b1bf-ac53592d86f6

The open-access MAF lists 34 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, Frame Shift Del 3, Intron 3, Frame Shift Ins 2, In Frame Del 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 140/419 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, varscan2
- PTEN | c.761_765del p.K254Rfs*42 | Frame Shift Del (DEL) | VAF 58/190 reads (31%) | catalogued as rs606231169; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- APC | c.4483dup p.S1495Kfs*19 | Frame Shift Ins (INS) | VAF 15/53 reads (28%) | catalogued as COSV99969088; called by mutect2*, pindel, varscan2*
- ATP2B3 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.6); PolyPhen benign (0.017); catalogued as rs782779816, COSV54839830; called by muse, mutect2, varscan2
- EGFR | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 99/375 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51822498; called by muse, mutect2, varscan2
- FOXP1 | c.476del p.L159Yfs*47 | Frame Shift Del (DEL) | VAF 63/208 reads (30%) | catalogued as rs1559822148; called by mutect2, pindel, varscan2
- LDHAL6B | c.848T>C p.V283A | Missense Mutation (SNP) | VAF 70/285 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs761105128; called by muse, mutect2, varscan2
- MDGA1 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 67/199 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51798403; called by muse, mutect2, varscan2
- NAALAD2 | c.524T>A p.F175Y | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as COSV100428057; called by muse, varscan2
- NCKAP5L | c.2633C>T p.A878V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1458644494; called by muse, mutect2, varscan2
- PCDHB8 | c.1123G>C p.D375H | Missense Mutation (SNP) | VAF 126/1026 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50768444; called by muse, mutect2, varscan2
- RXFP3 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 142/319 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1291692182; called by muse, mutect2, varscan2
- USH2A | c.4208C>T p.S1403F | Missense Mutation (SNP) | VAF 78/310 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100243632; called by muse, mutect2, varscan2
- VAV1 | c.762G>T p.M254I | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1407473033; called by muse, mutect2
- WSCD1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs769801984, COSV58495317; called by muse, mutect2, varscan2
- APC | c.4478_4479insA p.E1494Gfs*20 | Frame Shift Ins (INS) | VAF 18/42 reads (43%) | called by mutect2, varscan2
- CDC73 | c.667_669del p.D223del | In Frame Del (DEL) | VAF 85/392 reads (22%) | called by mutect2, pindel, varscan2
- LOXHD1 | c.2295G>C p.W765C | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PEG3 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PROM2 | c.2121T>G p.N707K | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RPL5 | c.756del p.Y253Mfs*28 | Frame Shift Del (DEL) | VAF 28/130 reads (22%) | called by mutect2, pindel, varscan2
- SMARCA5 | c.2025T>G p.D675E | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TNRC6A | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AQP10 | c.660C>T p.G220= | Silent (SNP) | VAF 45/202 reads (22%) | called by muse, mutect2, varscan2
- CRY1 | c.1095G>A p.L365= | Silent (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- MYLK3 | c.1839G>A p.V613= | Silent (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- PCDHA8 | c.1038C>T p.N346= | Silent (SNP) | VAF 18/161 reads (11%) | catalogued as rs1157712945, COSV65336144; called by muse, mutect2, varscan2
- PPM1L | c.897G>A p.L299= | Silent (SNP) | VAF 54/231 reads (23%) | called by muse, mutect2, varscan2
- SPTBN5 | c.3105C>T p.C1035= | Silent (SNP) | VAF 84/323 reads (26%) | called by muse, mutect2, varscan2
- CCDC88A | c.5551+41C>T | Intron (SNP) | VAF 51/215 reads (24%) | catalogued as rs375237893; called by muse, varscan2
- CDH13 | c.45+92290C>A | Intron (SNP) | VAF 35/133 reads (26%) | called by muse, mutect2, varscan2
- CEP41 | c.*2843G>A | 3'UTR (SNP) | VAF 86/266 reads (32%) | called by muse, varscan2
- CYTH2 | c.353+11C>G | Intron (SNP) | VAF 21/60 reads (35%) | catalogued as rs377576153; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99790315 A>T | 5'Flank (SNP) | VAF 9/95 reads (9%) | catalogued as rs1356638709; called by mutect2, varscan2
